Somatic mutation profile of tumor specimen TCGA-DW-7963-01B (aliquot TCGA-DW-7963-01B-11D-A28G-10) from TCGA case TCGA-DW-7963, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 43.7 years (15,967 days).
Specimen TCGA-DW-7963-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93e4f580-5953-4bba-a99f-3c159330eab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7963-10C (Blood Derived Normal), aliquot TCGA-DW-7963-10C-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddf333b6-fe49-4d99-923f-1b62da713534

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKNA | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56311013; called by muse, mutect2, varscan2
- DNMT3B | c.2082G>C p.W694C | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52414967; called by muse, mutect2, varscan2
- DOP1B | c.5549C>T p.T1850I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771019010, COSV67692085; called by muse, mutect2, varscan2
- GAD2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV52150657; called by muse, mutect2, varscan2
- GNS | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV50693922; called by muse, mutect2, varscan2
- HECTD1 | c.6736C>T p.H2246Y | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.152); catalogued as COSV67945082; called by muse, mutect2, varscan2
- KIF7 | c.3055A>C p.K1019Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51537843; called by muse, mutect2
- L3MBTL1 | c.1642G>A p.V548M (on ENST00000418998 / NM_001377303.1; = p.V458M on NM_015478.7) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64227893; called by muse, varscan2
- OSBPL11 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56172304; called by muse, mutect2, varscan2
- RYR2 | c.3371C>G p.P1124R | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100769203, COSV63662051; called by muse, mutect2, varscan2
- STIM1 | c.1205T>G p.L402R | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56151563; called by muse, mutect2, varscan2
- USH2A | c.4778C>A p.T1593N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV56327789; called by muse, mutect2, varscan2
- ZBED4 | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs749694326, COSV53463671; called by muse, mutect2, varscan2
- F12 | c.120_123del p.T41Sfs*53 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- CEP290 | c.5574C>A p.T1858= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58348647; called by muse, mutect2, varscan2
- ECHDC2 | c.876A>G p.K292= (on ENST00000371522 / NM_001198961.2; = p.K261= on NM_018281.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV64300102; called by muse, mutect2, varscan2
- NPHP3 | c.1947T>A p.I649= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV58628004; called by muse, mutect2, varscan2
- OXER1 | c.321G>T p.L107= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV54309709; called by muse, mutect2, varscan2
- STMN4 | c.63C>T p.S21= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV56108192; called by muse, mutect2, varscan2
- TAF6 | c.1224C>T p.D408= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs148894017; called by muse, mutect2, varscan2
- ZDHHC7 | c.666C>T p.F222= | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as COSV58211669, COSV58211850; called by muse, mutect2, varscan2
